Somatic mutation profile of tumor specimen TCGA-AA-3814-01A (aliquot TCGA-AA-3814-01A-01W-0900-09) from TCGA case TCGA-AA-3814, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 85.9 years (31,380 days).
Specimen TCGA-AA-3814-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d66378d1-4ec6-468f-8127-094989b2be3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3814-10A (Blood Derived Normal), aliquot TCGA-AA-3814-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/976e5a9e-dfe4-42e0-95fe-d7a33c8eecbc

The open-access MAF lists 112 somatic variants for this specimen: 79 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 31, Nonsense Mutation 4, Frame Shift Ins 4, Splice Region 2, Intron 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4222G>T p.E1408* | Nonsense Mutation (SNP) | VAF 41/139 reads (29%) | hotspot (GDC flag); catalogued as CM106374, COSV57326063, COSV57397024; called by muse, mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- PCBP1 | c.305T>C p.L102P | Missense Mutation (SNP) | VAF 8/21 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57850093, COSV57850258, COSV57850830; called by muse, mutect2, varscan2
- TP53 | c.422G>C p.C141S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as CM993216, COSV52664953, COSV52926626, COSV53155598; called by muse, mutect2, varscan2
- ACKR3 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs201423512, COSV56022317; called by muse, mutect2, varscan2
- ADH1C | c.746A>T p.K249I | Missense Mutation (SNP) | VAF 120/395 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV72463504; called by muse, mutect2, varscan2
- AGL | c.2554C>A p.L852I | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.692); catalogued as COSV54054010; called by muse, mutect2, varscan2
- AHNAK2 | c.3628G>A p.D1210N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV60918684; called by muse, mutect2, varscan2
- AKAP13 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 40/179 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs774873759, COSV63473490; called by muse, varscan2
- ANO2 | c.850C>T p.R284C (on ENST00000356134 / NM_001278597.3; = p.R288C on NM_001278596.3) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1214934107, COSV59028614; called by muse, mutect2, varscan2
- APBB1IP | c.1333A>G p.T445A | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV66133359; called by muse, mutect2, varscan2
- ARHGAP9 | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 77/162 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761890422, COSV62723241; called by muse, mutect2, varscan2
- B4GALT3 | c.457C>A p.Q153K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV60527409; called by muse, mutect2, varscan2
- CASD1 | c.965T>C p.L322S | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99802475; called by muse, mutect2
- CCDC172 | c.760C>T p.L254F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.718); catalogued as COSV100319713, COSV60936821; called by muse, mutect2, varscan2
- CDC16 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as rs746190360, COSV52960168; called by muse, mutect2, varscan2
- CDON | c.3560G>A p.R1187H | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771268293, COSV54999188; called by muse, mutect2, varscan2
- CLTCL1 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 78/125 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as rs201700885, COSV54225453; called by muse, mutect2, varscan2
- CMYA5 | c.2614C>T p.L872F | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.025); catalogued as rs1310455462, COSV71406710; called by muse, mutect2, varscan2
- CXCL5 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as COSV56018333; called by muse, mutect2, varscan2
- CYP4F2 | c.1119C>A p.D373E | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.196); catalogued as COSV55619073, COSV55621718; called by muse, mutect2, varscan2
- DECR1 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55169179; called by muse, mutect2, varscan2
- DPP6 | c.923C>T p.P308L (on ENST00000377770 / NM_001364500.2; = p.P246L on NM_001936.5) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs537661099, COSV59621257; called by muse, mutect2, varscan2
- ECT2L | c.69C>A p.L23= | Splice Region (SNP) | VAF 9/36 reads (25%) | catalogued as COSV62885342; called by muse, mutect2, varscan2
- ERBB4 | c.1981C>G p.L661V | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.355); catalogued as COSV53544464; called by muse, mutect2, varscan2
- FAM234B | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs766526805, COSV52195300; called by muse, mutect2, varscan2
- FRMPD1 | c.2809C>T p.R937* | Nonsense Mutation (SNP) | VAF 31/95 reads (33%) | catalogued as rs777298287, COSV66699105; called by muse, mutect2, varscan2
- GLIPR2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100936918; called by muse, mutect2
- GRAMD1C | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.06); catalogued as COSV63983047; called by muse, varscan2
- GRIK3 | c.1690G>T p.D564Y | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66141483; called by muse, mutect2
- GRM7 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as COSV63148833; called by muse, mutect2
- HERC2 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs768897624, COSV55329512; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HNMT | c.423G>A p.M141I | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV54506091, COSV54508484; called by muse, mutect2, varscan2
- IBTK | c.1923_1924insG p.F642Vfs*29 | Frame Shift Ins (INS) | VAF 28/161 reads (17%) | catalogued as COSV100090465; called by mutect2, pindel, varscan2
- IL22 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV60160169; called by muse, mutect2, varscan2
- JCAD | c.1341G>T p.K447N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV64760231; called by muse, mutect2, varscan2
- KIF15 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.642); catalogued as rs369068128; called by muse, mutect2, varscan2
- KLF3 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54711262; called by muse, mutect2, varscan2
- KMT2C | c.13561G>A p.V4521I | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1472062297, COSV51454059; called by muse, mutect2
- LDHC | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as rs760395380, COSV55004394; called by muse, mutect2, varscan2
- LGALS1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as rs1389013302, COSV53222309; called by muse, mutect2, varscan2
- MAP2 | c.4166G>T p.W1389L | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1027144711, COSV99559094; called by muse, mutect2
- MAP2K4 | c.871T>C p.W291R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62258298, COSV62259990; called by muse, mutect2, varscan2
- MID2 | c.1067C>A p.A356D | Missense Mutation (SNP) | VAF 778/1181 reads (66%) | SIFT tolerated (0.71); PolyPhen benign (0.042); catalogued as COSV53311063; called by muse, mutect2, varscan2
- MYBPC1 | c.763G>A p.A255T (on ENST00000550270 / NM_206820.2; = p.A280T on NM_002465.4) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.626); catalogued as rs942272670, COSV100637872; called by muse, mutect2
- NPPA | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs202145205, COSV56740933; called by muse, mutect2, varscan2
- NTRK3 | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750055690, COSV58122146, COSV58132978; called by muse, mutect2, varscan2
- OR14C36 | c.808C>A p.L270M | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.028); catalogued as COSV58601607, COSV58601710; called by muse, mutect2, varscan2
- OR2T12 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs1356123924, COSV58778027; called by muse, varscan2
- OR5AP2 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756963104, COSV57257858; called by muse, mutect2, varscan2
- PCDH17 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs971203051, COSV100931432; called by muse, mutect2
- PHLDB2 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 104/370 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs534767460, COSV67312589; called by muse, mutect2, varscan2
- PKHD1 | c.11377G>A p.A3793T | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV64392702; called by muse, mutect2, varscan2
- PKHD1 | c.9640T>G p.C3214G | Missense Mutation (SNP) | VAF 119/262 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61881747; called by muse, mutect2, varscan2
- PXDNL | c.4017G>A p.R1339= | Splice Region (SNP) | VAF 37/102 reads (36%) | catalogued as COSV62486926; called by muse, mutect2, varscan2
- PXDNL | c.2833G>A p.A945T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV100685397, COSV62489203; called by muse, mutect2, varscan2
- RSPH4A | c.1022T>A p.L341H | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1263440360, COSV57635448; called by muse, mutect2, varscan2
- SCN11A | c.3620G>T p.C1207F | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs904970580, COSV56572349; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN7A | c.3268C>G p.P1090A | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.089); catalogued as rs1323819744, COSV69272551; called by muse, mutect2, varscan2
- SDK1 | c.3542C>T p.T1181M | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs1438033324, COSV67357293; called by muse, mutect2, varscan2
- SLC32A1 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as COSV54147178; called by muse, mutect2, varscan2
- SPEF2 | c.3038T>A p.V1013D | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61549341; called by muse, mutect2, varscan2
- SVEP1 | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as rs369953563, COSV100237179; called by muse, mutect2, varscan2
- TBX18 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs987207695, COSV63736139, COSV63737235; called by muse, mutect2, varscan2
- THAP12 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1365820769, COSV52611166; called by muse, mutect2, varscan2
- TMEM182 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs767689957, COSV68425032; called by muse, mutect2, varscan2
- URB2 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50997732; called by mutect2, varscan2
- VRTN | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1208336612, COSV56441774; called by muse, mutect2, varscan2
- WIZ | c.4084G>C p.E1362Q (on ENST00000673675 / NM_001371589.1; = p.E267Q on NM_021241.3) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.408); catalogued as COSV54608737; called by muse, mutect2, varscan2
- XDH | c.2473C>T p.R825* | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as rs748879270, CM118253, COSV101052117, COSV65146698; called by muse, mutect2, varscan2
- XIRP2 | c.557C>A p.S186* (on ENST00000628543; = p.S361* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 41/89 reads (46%) | catalogued as COSV54691184, COSV54709429; called by muse, mutect2, varscan2
- ZBTB40 | c.2945C>T p.T982M | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs773187426, COSV65145653; called by muse, mutect2, varscan2
- ZNF285 | c.899G>T p.S300I | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV58409501; called by muse, mutect2, varscan2
- ADAMTS20 | c.5016dup p.G1673Wfs*18 | Frame Shift Ins (INS) | VAF 27/113 reads (24%) | called by mutect2, pindel, varscan2
- APC | c.2548_2555dup p.R854Vfs*10 | Frame Shift Ins (INS) | VAF 23/92 reads (25%) | called by mutect2, varscan2
- MAGEB6B | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MAGEB6B | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 133/215 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- TNFAIP3 | c.1368dup p.P457Afs*16 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by pindel, varscan2
- WIPF2 | c.616_619del p.E206Nfs*31 | Frame Shift Del (DEL) | VAF 50/78 reads (64%) | called by mutect2, pindel, varscan2
- ATP4A | c.819C>T p.G273= | Silent (SNP) | VAF 29/138 reads (21%) | catalogued as rs755378042, COSV52867017, COSV52868682; called by muse, mutect2, varscan2
- BPIFC | c.918C>T p.T306= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs375648599, COSV55910832; called by muse, mutect2, varscan2
- CASR | c.735G>A p.Q245= | Silent (SNP) | VAF 23/277 reads (8%) | catalogued as rs1362875083, COSV56138598; called by muse, mutect2
- DFFB | c.330G>A p.E110= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs1037280222, COSV58860986; called by muse, mutect2, varscan2
- DUSP10 | c.831G>A p.K277= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as rs767093804, COSV60458301; called by muse, mutect2, varscan2
- FAM110B | c.522G>A p.P174= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs183366212, COSV64063953; called by muse, mutect2, varscan2
- FNDC1 | c.1197C>T p.Y399= | Silent (SNP) | VAF 63/362 reads (17%) | catalogued as rs377223835; called by muse, mutect2, varscan2
- GRIK2 | c.2091A>C p.S697= | Silent (SNP) | VAF 29/148 reads (20%) | catalogued as COSV59744374; called by muse, mutect2, varscan2
- IGF2R | c.2077C>T p.L693= | Silent (SNP) | VAF 6/134 reads (4%) | catalogued as COSV100807175; called by muse, mutect2
- IL12B | c.507G>A p.T169= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs369160771, COSV51455301; called by muse, mutect2, varscan2
- IQCA1 | c.1728G>A p.P576= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as rs374874665; called by muse, mutect2, varscan2
- ITIH3 | c.234C>T p.S78= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV56255979; called by muse, mutect2
- KCNH1 | c.1695C>T p.A565= (on ENST00000271751 / NM_172362.3; = p.A538= on NM_002238.4) | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs779603628, COSV55087253; called by muse, mutect2, varscan2
- KIAA1549L | c.4515C>T p.Y1505= (on ENST00000321505; = p.Y1802= on NM_012194.3) | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs551823874, COSV58587339; called by muse, mutect2
- LILRB2 | c.969C>A p.G323= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV100079196; called by muse, mutect2
- LIMK2 | c.468G>A p.P156= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs747002313, COSV59182990; called by muse, mutect2, varscan2
- MMP16 | c.309A>G p.V103= | Silent (SNP) | VAF 6/170 reads (4%) | catalogued as COSV99687180, COSV99687215; called by muse, mutect2
- PCDHA13 | c.1692G>A p.A564= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99165586; called by muse, mutect2, varscan2
- PCDHGA5 | c.186C>T p.R62= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs1182506562, COSV53960394; called by muse, mutect2, varscan2
- PNPLA3 | c.867G>A p.S289= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs139896256; called by muse, mutect2, varscan2
- PREX2 | c.3033C>G p.L1011= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV55778364; called by muse, mutect2, varscan2
- ROBO2 | c.3666C>T p.D1222= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs201339466; called by muse, mutect2, varscan2
- SCLY | c.132T>C p.Y44= (on ENST00000651534; = p.Y36= on NM_016510.7) | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99615506; called by muse, mutect2
- SEC14L4 | c.900C>A p.G300= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV55400200; called by muse, mutect2, varscan2
- SLC10A5 | c.739C>T p.L247= | Silent (SNP) | VAF 31/165 reads (19%) | catalogued as COSV72828401, COSV72828446; called by muse, mutect2, varscan2
- SLC2A14 | c.1287C>T p.A429= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs772402834, COSV61587039; called by muse, mutect2, varscan2
- SMC6 | c.2301G>A p.E767= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as rs750985291, COSV61175558; called by muse, mutect2, varscan2
- SYNPO2 | c.1356C>T p.D452= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as rs1175588972, COSV61108665; called by muse, mutect2, varscan2
- TMEM163 | c.330C>T p.S110= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs145798414, COSV99925625; called by muse, mutect2, varscan2
- TNR | c.2787C>T p.Y929= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs772789738, COSV54892354; called by muse, mutect2, varscan2
- TRPC3 | c.834C>T p.H278= (on ENST00000379645 / NM_001366479.2; = p.H205= on NM_003305.2) | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV53376858; called by muse, mutect2, varscan2
- PTPRU | c.2850+1702T>C | Intron (SNP) | VAF 5/29 reads (17%) | catalogued as COSV60529986; called by muse, mutect2, varscan2
- ZNF207 | c.-97G>A | 5'UTR (SNP) | VAF 14/22 reads (64%) | catalogued as rs750118944, COSV58300470; called by muse, mutect2, varscan2
